Gene-level copy-number profile of tumor specimen TCGA-CZ-5984-01A from TCGA case TCGA-CZ-5984, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 51.4 years (18,775 days).
Specimen TCGA-CZ-5984-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.0e52d456-fbb8-4004-b6bc-43d3c86379f5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CZ-5984-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b099ad7a-faea-4576-b211-b66460bd6b35

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 912; copy number 2: 12,733; copy number 3: 27,574; copy number 4: 17,256; copy number 6: 1,113; copy number 7: 232.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CZ-5984-01A-11D-1668-01): tumor purity 0.52, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 232 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:114,475,339–131,008,742, 213 genes, copy number 7 (broad region; genes not listed).
- chr5:164,296,696–167,168,401, 16 genes, copy number 7 (within-gene range 6–7): AC109466.1, LINC02143, AC008446.1, RNU6-209P, AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947, AC091819.2, AC091819.1.
- chr5:167,287,320–167,309,870, 3 genes, copy number 7: AC091820.2, AC091820.1, AC008601.1.

Autosomal genes at a single copy (total copy number 1): 912. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
